Gene-level copy-number profile of tumor specimen MP2PRT-PARPCA-TMP1-A from MP2PRT case MP2PRT-PARPCA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,176 days).
Specimen MP2PRT-PARPCA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c6daef50-44ba-405e-bd84-affff53f0775.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARPCA-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/0424ed65-9297-42da-a50d-0ee0cc3a59b3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 134; copy number 1: 406; copy number 2: 57,697; copy number 3: 151.

Homozygous deletions (total copy number 0; autosomes only): 134 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,825,207, 2 genes (within-gene range 0–2): MALLP2, MIR4436A.
- chr2:89,159,751–89,196,829, 6 genes (within-gene range 0–1): IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26.
- chr14:22,155,079–22,552,156, 88 genes (within-gene range 0–2) (broad region; genes not listed).
- chr22:22,168,289–22,245,515, 12 genes: AC245517.2, SOCS2P2, IGLVIV-59, IGLVV-58, BMP6P1, IGLV6-57, IGLVI-56, IGLV11-55, IGLVIV-53, TOP3BP1, AC245060.3, VPREB1.
- chr22:22,738,944–22,755,797, 3 genes (within-gene range 0–1): IGLV3-17, IGLV3-16, IGLV3-15.
- chr22:22,762,294–22,896,111, 23 genes: IGLV3-13, IGLV3-12, AC244157.1, AC244157.2, IGLV2-11, AC245028.3, IGLV3-10, AC245028.1, IGLV3-9, IGLV2-8, MIR650, AC245028.2, IGLV3-7, IGLV3-6, IGLV2-5, IGLV3-4, IGLV4-3, IGLV3-2, IGLV3-1, MIR5571, IGLL5, IGLJ1, IGLC1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 406. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
